Gene-level copy-number profile of tumor specimen TCGA-N8-A4PO-01A from TCGA case TCGA-N8-A4PO, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Isthmus uteri; FIGO stage: Stage II; Age at diagnosis: 66.0 years (24,124 days).
Specimen TCGA-N8-A4PO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.4986493a-fdda-4223-ba72-f485d67b369e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N8-A4PO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64c22122-df18-46af-b862-057b383c253a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 4,576; copy number 2: 24,210; copy number 3: 15,524; copy number 4: 10,872; copy number 5: 3,483; copy number 6: 886; copy number 7: 141; copy number 8: 66; copy number 9: 12; copy number 10: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N8-A4PO-01A-11D-A28Q-01): tumor purity 0.93, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,389,567–48,444,704, 2 genes (within-gene range 0–2): LPAR6, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,624 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,745,829–156,177,752, 23 genes, copy number 6: MSTO2P, GON4L, AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A.
- chr3:13,549,125–14,178,621, 13 genes, copy number 5 (within-gene range 3–5): FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC.
- chr3:125,225,669–198,222,513, 1,337 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–36,347,157, 558 genes, copy number 5 (broad region; genes not listed).
- chr6:11,173,452–11,644,343, 10 genes, copy number 6 (within-gene range 4–6): AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP.
- chr6:158,515,605–159,272,108, 24 genes, copy number 5 (within-gene range 4–5): CACYBPP3, TMEM181, TATDN2P2, MIR7161, DYNLT1, SYTL3, AMZ2P2, MIR3918, EZR, EZR-AS1, OSTCP1, AL627422.2, C6orf99, AL627422.1, RNU6-293P, RSPH3, AL035530.2, TAGAP, AL035530.1, AL356417.3, AL356417.1, AL356417.2, FNDC1, FNDC1-IT1.
- chr7:63,011,463–63,636,617, 39 genes, copy number 5: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2, SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1.
- chr8:42,537,529–132,675,592, 1,298 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr8:135,859,369–145,066,685, 225 genes, copy number 5 (broad region; genes not listed).
- chr11:46,920,880–54,725,816, 135 genes, copy number 5 (broad region; genes not listed).
- chr12:220,621–1,495,933, 18 genes, copy number 5–6 (within-gene range 2–6): SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1.
- chr12:1,380,060–1,918,666, 13 genes, copy number 6 (within-gene range 2–6): AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2.
- chr12:2,786,931–5,244,199, 69 genes, copy number 5 (broad region; genes not listed).
- chr12:5,315,961–5,319,347, 1 gene, copy number 5: AC006206.1.
- chr13:43,883,800–44,028,526, 1 gene, copy number 5 (within-gene range 2–5): AL512506.3.
- chr13:43,908,669–44,405,984, 12 genes, copy number 5 (within-gene range 2–5): NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2, TUSC8.
- chr14:35,121,846–35,317,474, 2 genes, copy number 6 (within-gene range 3–6): PRORP, AL121594.1.
- chr14:35,157,904–35,469,330, 12 genes, copy number 6: SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4.
- chr17:17,674,026–18,842,364, 68 genes, copy number 5 (broad region; genes not listed).
- chr17:18,840,618–18,840,920, 1 gene, copy number 5: RN7SL627P.
- chr17:19,868,568–21,419,870, 77 genes, copy number 5 (broad region; genes not listed).
- chr17:21,442,805–21,460,215, 4 genes, copy number 5: AC068418.3, PDLIM1P2, AC068418.2, AC068418.1.
- chr18:47,390–15,330,282, 376 genes, copy number 5–8 (broad region; genes not listed).
- chr19:19,254,748–24,163,425, 231 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–2,641,784, 77 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,679. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
